FM case AD17858 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Basal Cell Neoplasms; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/6591869f-5db4-4155-9a5e-9a5b32c6606f

Male, 46.8 years: Basal cell carcinoma, NOS (ICD-O-3 8090/3) of the skin; primary biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
